Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A3HU, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A3HU-01A (Primary Tumor).

Procurement Date: laterality:

Path Report: UTERUS TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy

Tumor site: Cervix

Tumor size: 5 x 4 x 2.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Greater than 1/2 myometrium

Lymph nodes: 0/14 positive for metastasis (Regional 0/14)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Extent of myometrial invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Gross Description:

Microscopic Description:

Diagnosis Details:

ICD-O-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53-9
w
12/1/11

Source: NCI Genomic Data Commons file 64f4ef7f-e7d8-4a61-a8ce-e94e0b116eef (TCGA-EA-A3HU.3A6FE044-430D-4D43-9365-9FA788758BE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).